CPTAC case C3N-08896 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/124227e6-edb2-45e9-aa19-ab3a5bbd0c60

Demographics
Sex at birth: female; Race: white; Year of birth: 1965; Vital status: Dead; Days to death: 355 days; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 56.9 years (20,765 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic stage: Stage IA; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 355 days; Progression or recurrence: no; Days to last follow up: 355 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 24.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 21 days; Days to treatment end: 110 days; Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 355 days; Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-08896-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 210 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-08896-21: Section location: Stomach, NOS; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-08896-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
